FM case AD9545 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/abe379fe-9193-4365-ae8f-40c1094e5d55

Female, 36.8 years: Papillary carcinoma, NOS (ICD-O-3 8050/3) of the thyroid gland; metastasis biopsied or resected from the thyroid gland. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
